Somatic mutation profile of tumor specimen MP2PRT-PAPWML-TMP1-A (aliquot MP2PRT-PAPWML-TMP1-A-1-0-D-A83N-36) from MP2PRT case MP2PRT-PAPWML, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.4 years (3,085 days).
Specimen MP2PRT-PAPWML-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9e6a7fab-1b61-4523-a25a-19af21c7c92b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPWML-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPWML-NB1-A-1-0-D-A83N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d28eaa1c-8b71-4015-887b-36a7bcb7b645

The open-access MAF lists 19 somatic variants for this specimen: 15 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 13, Silent 4, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DEFB112 | c.238G>C p.D80H | Missense Mutation (SNP) | VAF 78/301 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV104399134; called by muse, mutect2, varscan2
- GRM6 | c.589G>A p.D197N | Missense Mutation (SNP) | VAF 120/348 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs140082247; called by muse, mutect2, varscan2
- GRXCR2 | c.49C>T p.R17W | Missense Mutation (SNP) | VAF 92/291 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs376301264; called by muse, mutect2, varscan2
- KRT37 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 158/581 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs369798171, COSV99845408; called by muse, mutect2, varscan2
- MET | c.665C>T p.T222M | Missense Mutation (SNP) | VAF 128/474 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs200776610; ClinVar: likely benign / uncertain significance; called by muse, varscan2
- NF1 | c.2851-1G>A p.X951_splice | Splice Site (SNP) | VAF 71/233 reads (30%) | catalogued as CD000081, CS1311517, COSV62220039; called by muse, mutect2, varscan2
- PDZRN3 | c.2830C>T p.R944W | Missense Mutation (SNP) | VAF 142/386 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs750997558, COSV55205737; called by muse, varscan2
- PXDN | c.2699G>A p.R900Q | Missense Mutation (SNP) | VAF 143/391 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757339869, COSV53245305; called by muse, mutect2, varscan2
- TACC2 | c.8642C>T p.A2881V (on ENST00000334433; = p.A959V on NM_006997.4) | Missense Mutation (SNP) | VAF 78/350 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779013734; called by muse, mutect2, varscan2
- TRAM1L1 | c.1045G>A p.G349R | Missense Mutation (SNP) | VAF 120/314 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV60291867; called by muse, mutect2, varscan2
- FBXO30 | c.1838T>C p.L613P | Missense Mutation (SNP) | VAF 92/387 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- G3BP1 | c.808A>C p.I270L | Missense Mutation (SNP) | VAF 13/253 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.005); called by muse, mutect2
- HOXB3 | c.513_518del p.G177_G178del | In Frame Del (DEL) | VAF 113/526 reads (21%) | called by mutect2, pindel, varscan2
- IZUMO3 | c.436T>A p.C146S (on ENST00000543880 / NM_001365008.2; = p.C140S on NM_001271706.1) | Missense Mutation (SNP) | VAF 86/311 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- ZMIZ1 | c.878C>A p.A293D | Missense Mutation (SNP) | VAF 159/625 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- EPHB1 | c.2283C>T p.S761= | Silent (SNP) | VAF 127/337 reads (38%) | catalogued as rs555858727, COSV101213411, COSV67654919; called by muse, mutect2, varscan2
- ITPR1 | c.3207G>A p.T1069= (on ENST00000354582; = p.T1054= on NM_002222.7) | Silent (SNP) | VAF 133/353 reads (38%) | catalogued as rs774079144, COSV56976603; called by muse, mutect2, varscan2
- TMEM108 | c.1080C>A p.T360= | Silent (SNP) | VAF 90/331 reads (27%) | called by muse, mutect2, varscan2
- ZAN | c.1761C>T p.P587= | Silent (SNP) | VAF 164/683 reads (24%) | called by muse, mutect2, varscan2
